Gene-level copy-number profile of tumor specimen TCGA-23-1028-01A from TCGA case TCGA-23-1028, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 43.9 years (16,018 days).
Specimen TCGA-23-1028-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.773bff37-5ef8-462d-b742-56db7a09015a.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-23-1028-10B (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/02a9aa39-bcba-4c33-891f-e9a089f3c1b5

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 4; copy number 1: 20,429; copy number 2: 33,899; copy number 3: 4,804; copy number 4: 621; copy number 5: 55.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-23-1028-01): tumor purity 0.82, ploidy 1.74, whole-genome doublings 0 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): 4 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:58,643,440–58,784,048, 3 genes (within-gene range 0–1): MYSM1, AL136985.3, JUN.
- chr1:58,812,808–58,813,342, 1 gene: AL136985.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 55 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:144,683,169–145,066,685, 22 genes, copy number 5: Metazoa_SRP, AF186192.1, AF186192.2, AF186192.3, ZNF251, ZNF34, RN7SL395P, RPL8, MIR6850, ZNF517, ZNF7, COMMD5, AF235103.3, ZNF250, ZNF16, ZNF252P, AF235103.1, TMED10P1, ZNF252P-AS1, AF235103.2, AC139103.1, C8orf33.
- chr17:142,789–1,229,738, 33 genes, copy number 5 (within-gene range 3–5): DOC2B, LINC02091, RPH3AL, AC129507.4, AC129507.1, AC129507.2, AC129507.3, AC141424.1, C17orf97, RFLNB, AC015853.2, VPS53, AC015853.3, AC015853.1, AC027455.1, RPS4XP17, TLCD3A, GEMIN4, DBIL5P, GLOD4, AC087392.3, MRM3, AC087392.4, AC087392.5, NXN, AC087392.2, AC087392.1, AC036164.1, TIMM22, ABR, MIR3183, Metazoa_SRP, AC016292.2.

Autosomal genes at a single copy (total copy number 1): 19,939. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
